Somatic mutation profile of tumor specimen TCGA-CQ-6227-01A (aliquot TCGA-CQ-6227-01A-11D-1912-08) from TCGA case TCGA-CQ-6227, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 77.9 years (28,466 days).
Specimen TCGA-CQ-6227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6edf3f59-bd55-4d08-8f55-1b467cae51f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6227-10A (Blood Derived Normal), aliquot TCGA-CQ-6227-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46932b2d-3ebb-4f25-976b-1c1a949b711a

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 4, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACIN1 | c.2878T>A p.L960M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99399464; called by muse, mutect2, varscan2
- AQP1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548913885, COSV100310897; called by mutect2, varscan2
- B3GNT3 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as rs1234458720, COSV100592712; called by muse, mutect2
- CABP7 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs1166201711, COSV99334764; called by muse, mutect2, varscan2
- CALCA | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100523994; called by muse, mutect2, varscan2
- CCKAR | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1413472220, COSV99810249; called by muse, mutect2, varscan2
- CDC7 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99319692; called by muse, mutect2, varscan2
- CNTRL | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53052095; called by muse, mutect2, varscan2
- CYP1B1 | c.-1-1G>A | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99572666; called by muse, mutect2, varscan2
- DMXL2 | c.8971C>T p.R2991* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs775750727, COSV51840432; called by mutect2, varscan2
- DUSP2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99997046; called by muse, mutect2, varscan2
- DVL1 | c.1304T>G p.M435R (on ENST00000378888 / NM_001330311.2; = p.M410R on NM_004421.3) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100229439; called by muse, mutect2, varscan2
- EXD2 | c.871C>G p.P291A (on ENST00000312994 / NM_001193362.1; = p.P166A on NM_018199.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100473999, COSV57278280; called by muse, mutect2, varscan2
- FGF19 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as COSV99594322; called by muse, mutect2, varscan2
- GRIK1 | c.2295C>A p.C765* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs1007331435, COSV100516546; called by muse, mutect2, varscan2
- HOXC6 | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99679016; called by muse, mutect2
- KIAA0100 | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101197286; called by muse, mutect2, varscan2
- LAD1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs138881525; called by muse, mutect2, varscan2
- MICALL1 | c.2028C>G p.D676E | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99317214; called by muse, mutect2, varscan2
- MYLK3 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs771870674, COSV67366589; called by muse, mutect2, varscan2
- OR10AD1 | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as rs780762242, COSV100046760; called by muse, mutect2, varscan2
- SHANK1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1461340322, COSV99520935; called by muse, mutect2, varscan2
- SLC13A4 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs769333711, COSV62459878; called by muse, mutect2, varscan2
- SLC28A1 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV99722897; called by muse, mutect2, varscan2
- TRIM42 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as rs1408160535, COSV53884893; called by muse, mutect2, varscan2
- TRIM50 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV100297045, COSV60791399; called by muse, mutect2, varscan2
- TUFM | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916839726, COSV57949119; called by muse, mutect2, varscan2
- UBIAD1 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245495523, COSV100954850, COSV65147920; called by muse, mutect2, varscan2
- WASHC5 | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749402075, COSV100572781; called by muse, mutect2, varscan2
- WFDC8 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.079); catalogued as COSV99250398; called by muse, mutect2, varscan2
- ZNF568 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as rs565321465, COSV61741373; called by muse, mutect2, varscan2
- ZNF618 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV99929932; called by muse, mutect2, varscan2
- MAP3K15 | c.2780C>G p.P927R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- TEK | c.3123del p.M1042* | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- BCHE | c.1461C>T p.A487= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs74458984, COSV52255355, COSV52255362; called by muse, mutect2, varscan2
- CLPB | c.249C>A p.L83= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV53628020, COSV53632212, COSV99577898; called by muse, mutect2, varscan2
- DNAJC11 | c.1218G>C p.L406= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99602115, COSV99602139; called by muse, mutect2, varscan2
- EVPL | c.2721T>C p.P907= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100044381; called by muse, mutect2, varscan2
- GPRC5A | c.391C>T p.L131= | Silent (SNP) | VAF 55/252 reads (22%) | catalogued as COSV99185552; called by muse, mutect2, varscan2
- H2AC17 | c.81T>C p.P27= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs758776626, COSV100377574; called by muse, mutect2, varscan2
- MEAK7 | c.717C>A p.G239= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100640390; called by muse, mutect2, varscan2
- PARP3 | c.399C>A p.T133= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as COSV51753982, COSV99232354; called by muse, mutect2, varscan2
- SLC7A8 | c.714C>T p.F238= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV100328380; called by muse, mutect2
- SLCO2B1 | c.1113C>T p.P371= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV99214560; called by muse, mutect2, varscan2
- ZNF17 | c.171G>A p.E57= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV100300022; called by muse, mutect2, varscan2
- THRA | c.1110+104T>G | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99225437; called by muse, mutect2, varscan2
